Somatic mutation profile of tumor specimen TCGA-EI-7004-01A (aliquot TCGA-EI-7004-01A-11D-1924-10) from TCGA case TCGA-EI-7004, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; Age at diagnosis: 37.1 years (13,566 days).
Specimen TCGA-EI-7004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6c38567-d5ed-4f04-a932-da28535486e3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EI-7004-10A (Blood Derived Normal), aliquot TCGA-EI-7004-10A-01D-1924-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9bc037fa-cd78-4553-8d48-f43d38db8861

The open-access MAF lists 93 somatic variants for this specimen: 72 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 18, Nonsense Mutation 6, Translation Start Site 1, In Frame Del 1, RNA 1, Frame Shift Ins 1, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATM | c.8624A>G p.N2875S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782451, CD120363, CM102244, COSV53726848, COSV53730217; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACSM2A | c.1427C>T p.S476L (on ENST00000219054; = p.S397L on NM_001308169.2) | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.019); catalogued as rs75603553, COSV54585974, COSV99524758; called by muse, varscan2
- ACSM2A | c.1501C>T p.R501* (on ENST00000219054; = p.R422* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 14/86 reads (16%) | catalogued as rs376967417, COSV54582297; called by muse, varscan2
- ALMS1 | c.4813G>A p.E1605K | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV52502969; called by muse, mutect2, varscan2
- ARPP21 | c.1583C>T p.P528L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.098); catalogued as rs142886822; called by muse, mutect2, varscan2
- ATG13 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1442396941, COSV56317472; called by muse, mutect2, varscan2
- BICRAL | c.533C>A p.A178E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV58403576; called by muse, mutect2, varscan2
- C1D | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 30/155 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV63412931; called by muse, mutect2, varscan2
- C9orf43 | c.729T>A p.N243K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55911839; called by muse, mutect2, varscan2
- CCDC191 | c.2140G>A p.E714K | Missense Mutation (SNP) | VAF 61/313 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV55670153; called by muse, mutect2, varscan2
- CDH4 | c.2554G>A p.A852T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373341715, COSV64658317; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDYL2 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs1161870624, COSV73653843; called by muse, mutect2, varscan2
- CEP63 | c.2101G>C p.A701P | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV59674443; called by muse, mutect2, varscan2
- CFAP91 | c.1829G>A p.R610Q | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs144518308; called by muse, mutect2, varscan2
- CNTFR | c.293G>A p.R98H | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1347465554, COSV63633151; called by muse, mutect2, varscan2
- COL1A2 | c.2698G>T p.A900S | Missense Mutation (SNP) | VAF 38/196 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51953064, COSV51967161; called by muse, mutect2, varscan2
- COL6A6 | c.6633_6635del p.E2211del | In Frame Del (DEL) | VAF 17/81 reads (21%) | catalogued as rs986745851; called by pindel, varscan2
- CSAD | c.673G>A p.E225K (on ENST00000444623 / NM_001244705.2; = p.E252K on NM_015989.5) | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as COSV57241386; called by muse, mutect2, varscan2
- DPP9 | c.59C>T p.P20L (on ENST00000598800; = p.P49L on NM_139159.5) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs781767492, COSV53589229; called by muse, mutect2, varscan2
- DSC3 | c.1167G>A p.W389* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV64571761; called by muse, mutect2, varscan2
- EPHB1 | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs186851943, COSV67654218; called by muse, mutect2, varscan2
- ERBB4 | c.2564A>C p.N855T | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV61464053; called by muse, mutect2, varscan2
- EYS | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60996738; called by muse, mutect2, varscan2
- FBXL7 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs768979466, COSV61641355; called by muse, mutect2, varscan2
- FOXRED2 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV53398878; called by muse, mutect2, varscan2
- GABRR3 | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs755217153, COSV101512343; called by muse, mutect2, varscan2
- GDF3 | c.341C>G p.S114C | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61711849; called by muse, mutect2, varscan2
- GNL1 | c.604G>T p.V202L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64835062; called by muse, mutect2, varscan2
- GPR6 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV51571060; called by muse, mutect2, varscan2
- GRIA2 | c.685C>A p.H229N | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0.245); catalogued as COSV52382710; called by muse, varscan2
- H2BC14 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.005); catalogued as COSV60797186; called by muse, mutect2, varscan2
- HAND2 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64017748; called by muse, mutect2, varscan2
- IBSP | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs748954490, COSV56894710, COSV56896288; called by muse, mutect2, varscan2
- LRRC3B | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67520098, COSV67522881; called by muse, mutect2, varscan2
- LTF | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371681789; called by muse, mutect2, varscan2
- MATN4 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | PolyPhen possibly damaging (0.532); catalogued as rs918268552, COSV59212726; called by muse, mutect2, varscan2
- MDM1 | c.2062C>A p.R688S | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57444506; called by muse, mutect2, varscan2
- MORC1 | c.2201G>T p.S734I | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV51714114; called by muse, mutect2
- MUC16 | c.3695C>A p.S1232* | Nonsense Mutation (SNP) | VAF 19/78 reads (24%) | catalogued as COSV67445555; called by muse, mutect2, varscan2
- MYEF2 | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs756119377, COSV51045980; called by muse, mutect2, varscan2
- MYH6 | c.3551C>T p.T1184M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs112883817, COSV100676872; called by muse, mutect2, varscan2
- MYL4 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs375241929; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKX6-1 | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 40/115 reads (35%) | catalogued as COSV55684029; called by muse, mutect2, varscan2
- NLGN4X | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 87/271 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as CM132234, COSV52005045; called by muse, mutect2, varscan2
- OR4S1 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV60678712; called by muse, mutect2, varscan2
- OR52E2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV58611824; called by muse, mutect2, varscan2
- PACS1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.815); catalogued as COSV57696187; called by muse, mutect2, varscan2
- PEX5L | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99829521; called by muse, mutect2, varscan2
- PLXNB2 | c.4171C>T p.R1391C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466531970, COSV63780507; called by muse, mutect2
- PPHLN1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377621404; called by muse, mutect2, varscan2
- PRDM9 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV57002658; called by muse, mutect2, varscan2
- RAB33B | c.620T>G p.L207R | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as COSV59777084; called by muse, mutect2, varscan2
- RABGGTB | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.282); catalogued as COSV54196774; called by muse, mutect2, varscan2
- RNF43 | c.127del p.E43Nfs*8 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | catalogued as COSV60415193, COSV60419914; called by mutect2, pindel, varscan2
- SCN10A | c.3440G>A p.R1147H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.04); catalogued as rs375926577, COSV101479488; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCN9A | c.1482G>T p.K494N | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.589); catalogued as rs777699798, COSV57600541; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- SH3GL2 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180303494, COSV66047769, COSV66055997; called by muse, mutect2, varscan2
- SLX4 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs978074181, COSV53560992; called by muse, mutect2, varscan2
- SNUPN | c.922C>A p.Q308K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV57947501; called by muse, mutect2, varscan2
- SPTY2D1 | c.1234A>G p.I412V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs201954599; called by muse, mutect2, varscan2
- SYNGAP1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99538814; called by muse, mutect2, varscan2
- SYTL1 | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV58870234; called by muse, mutect2, varscan2
- TENM3 | c.6233C>T p.T2078M | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767821436, COSV69299601; called by muse, mutect2, varscan2
- THRA | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1475640902, COSV52840784; called by muse, mutect2, varscan2
- TNNI2 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV53288683; called by muse, mutect2, varscan2
- USP7 | c.3300C>G p.I1100M | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61212979; called by muse, mutect2, varscan2
- VRTN | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs1354661608, COSV56439277; called by muse, mutect2, varscan2
- ZNF304 | c.794C>A p.A265D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV56583283; called by muse, mutect2, varscan2
- ZNF428 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as rs1260892028, COSV56192621; called by muse, mutect2, varscan2
- ZSCAN18 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53729722; called by muse, mutect2, varscan2
- CLCN3 | c.2173_2177dup p.I726Mfs*26 | Frame Shift Ins (INS) | VAF 32/74 reads (43%) | called by mutect2, pindel, varscan2
- TIMM23 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 329/1253 reads (26%) | called by muse, mutect2, varscan2
- ASTN1 | c.621G>A p.V207= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV56083544; called by muse, mutect2
- COL20A1 | c.1086G>T p.G362= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV58911894; called by muse, mutect2
- EPHA7 | c.2667T>A p.I889= | Silent (SNP) | VAF 39/155 reads (25%) | catalogued as COSV65177491; called by muse, mutect2, varscan2
- EXOC3L2 | c.1203G>A p.E401= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV99374609; called by muse, mutect2
- FCAR | c.696C>T p.A232= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs769864643, COSV62028362, COSV62031267; called by muse, mutect2, varscan2
- FOXG1 | c.129C>T p.H43= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV100487008; called by muse, varscan2
- FRMPD3 | c.4680C>T p.G1560= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV99346838; called by muse, mutect2, varscan2
- GLI3 | c.3396C>T p.P1132= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs1053587562, COSV67885367; called by muse, mutect2, varscan2
- KIF16B | c.462T>C p.Y154= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV61701487; called by muse, mutect2, varscan2
- NAGA | c.999C>T p.N333= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as COSV67169723; called by muse, mutect2, varscan2
- NALCN | c.2160G>T p.L720= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99216899; called by muse, mutect2
- NDN | c.774C>T p.Y258= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as COSV59358457; called by muse, mutect2, varscan2
- NSUN6 | c.1203G>A p.P401= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as rs773202318, COSV66031837, COSV66035794; called by muse, mutect2, varscan2
- OLFML2A | c.1908C>T p.Y636= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs757608633, COSV56581950; called by muse, mutect2, varscan2
- PCDHB2 | c.1506C>T p.L502= | Silent (SNP) | VAF 59/95 reads (62%) | catalogued as rs1554271463, COSV50564243; called by muse, mutect2, varscan2
- PCSK2 | c.987C>A p.I329= | Silent (SNP) | VAF 14/49 reads (29%) | catalogued as COSV52726590; called by muse, mutect2, varscan2
- PNKP | c.1401G>A p.T467= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs374547164; ClinVar: likely benign; called by muse, mutect2
- ST6GAL1 | c.957C>T p.N319= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as rs377592687; called by muse, mutect2, varscan2
- DCHS2 | n.664C>T | RNA (SNP) | VAF 15/47 reads (32%) | catalogued as rs756567652, COSV59718576; called by muse, mutect2, varscan2
- FABP6 | c.-9C>T | 5'UTR (SNP) | VAF 22/104 reads (21%) | catalogued as COSV67436686; called by muse, mutect2, varscan2
- PARVB | c.*1C>T | 3'UTR (SNP) | VAF 12/34 reads (35%) | catalogued as rs202107553; called by muse, mutect2, varscan2
